Gene-level copy-number profile of tumor specimen TCGA-DD-A73F-01A from TCGA case TCGA-DD-A73F, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 77.3 years (28,234 days).
Specimen TCGA-DD-A73F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.e64ec94a-f322-4a28-abef-040237db2cb7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A73F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06bf54b2-3f44-483f-9d54-5dea1815822e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 4,513; copy number 2: 53,978; copy number 3: 1,308; copy number 4: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A73F-01A-11D-A32F-01): tumor purity 0.68, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,280,764–15,619,819, 3 genes: RNA5SP475, AL121584.1, ENSAP1.
- chr22:31,676,256–31,908,033, 2 genes (within-gene range 0–3): PRR14L, DEPDC5.
- chr22:31,757,202–31,837,298, 3 genes: RN7SL20P, AL022331.1, RNU6-201P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,513. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
